Somatic mutation profile of tumor specimen 0DX0QW from CCDI case PBCNSN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.4 years (1,606 days).
Specimen 0DX0QW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d295ba92-889b-42ed-95ab-006616eedd80.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DX0Q1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1770e7f6-7b6c-4f18-ba3f-7857f5a1686e

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 2, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARMC7 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 80/966 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- NR1D2 | c.1192G>A p.G398R | Missense Mutation (SNP) | VAF 30/764 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.406); called by muse, mutect2
- OR5V1 | c.598C>G p.L200V | Missense Mutation (SNP) | VAF 48/506 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.57); called by muse, mutect2
- PALLD | c.571A>T p.R191* | Nonsense Mutation (SNP) | VAF 36/397 reads (9%) | called by muse, mutect2
- NLRC3 | c.597G>A p.P199= | Silent (SNP) | VAF 12/176 reads (7%) | catalogued as rs1464956407, COSV57094314; called by muse, mutect2
- EIF3I | c.251-93A>T | Intron (SNP) | VAF 4/19 reads (21%) | called by muse, varscan2
- HMGA2 | c.250-36219T>G | Intron (SNP) | VAF 53/212 reads (25%) | catalogued as rs767674875; called by muse, mutect2, varscan2
